Gene-level copy-number profile of tumor specimen TCGA-IK-7675-01A from TCGA case TCGA-IK-7675, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 43.5 years (15,900 days).
Specimen TCGA-IK-7675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.92081ad5-d23d-478a-b39e-e5b0310715cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IK-7675-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5082fea3-a215-4fc5-9551-0168cafbdfa2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 8,926; copy number 2: 49,059; copy number 3: 1,743; copy number 4: 28; copy number 5: 16; copy number 12: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IK-7675-01A-11D-2085-01): tumor purity 1, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,764,391–190,092,279, 23 genes (within-gene range 0–1): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:98,943,179–99,070,792, 1 gene, copy number 5 (within-gene range 2–5): COL15A1.
- chr9:99,104,038–99,906,605, 15 genes, copy number 5 (within-gene range 2–5): TGFBR1, RNA5SP290, AL162427.1, RN7SL794P, ALG2, SEC61B, RN7SKP225, KRT8P11, NAMA, AL137067.2, AL137067.3, AL137067.1, AL359710.1, STX17-AS1, AL162394.1.
- chr12:57,674,665–57,959,148, 25 genes, copy number 12 (within-gene range 3–12): RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.

Autosomal genes at a single copy (total copy number 1): 7,091. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
